Gene-level copy-number profile of tumor specimen ALCH-B1OR-TTR1-A from ALCHEMIST case ALCH-B1OR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.6 years (29,803 days).
Specimen ALCH-B1OR-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 817cb61e-f3c4-4a9f-a7b5-9a38d0b3d5b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/5dd1719d-e0ad-437d-8e3f-d9227763eff6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 2,784; copy number 2: 22,182; copy number 3: 20,827; copy number 4: 7,587; copy number 5: 4,082; copy number 6: 728; copy number 7: 9; copy number 8: 47; copy number 11: 1; copy number 18: 1; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,244,865, 5 genes (within-gene range 0–1): ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P.
- chr8:22,024,125–22,232,101, 13 genes: NPM2, FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP.
- chr8:43,292,483–43,674,591, 14 genes: POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr9:61,659,733–61,662,690, 1 gene: AL935212.1.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr14:23,372,809–23,376,403, 1 gene: IL25.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–1): AC092143.1, AC092143.2, TUBB3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,865 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–170,085,208, 999 genes, copy number 5 (broad region; genes not listed).
- chr1:173,141,100–207,184,062, 606 genes, copy number 5 (broad region; genes not listed).
- chr2:89,252,211–89,310,144, 8 genes, copy number 5: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:153,761,450–196,593,684, 560 genes, copy number 5 (broad region; genes not listed).
- chr6:24,171,755–29,885,615, 296 genes, copy number 5 (broad region; genes not listed).
- chr6:29,941,260–60,546,660, 816 genes, copy number 5 (broad region; genes not listed).
- chr8:72,947,150–83,294,271, 161 genes, copy number 5 (broad region; genes not listed).
- chr8:109,899,246–116,944,487, 41 genes, copy number 5: AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr8:122,485,194–122,733,804, 1 gene, copy number 5 (within-gene range 4–5): LINC01151.
- chr8:122,671,291–125,541,373, 76 genes, copy number 5 (broad region; genes not listed).
- chr8:143,716,340–143,790,645, 6 genes, copy number 6 (within-gene range 4–6): MAPK15, AC105219.1, FAM83H, MIR4664, IQANK1, AC105219.3.
- chr9:40,121,962–40,122,540, 1 gene, copy number 31: CDRT15P14.
- chr9:61,190,003–61,453,030, 7 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,642,494, 2 genes, copy number 6: FAM242D, Y_RNA.
- chr9:61,665,579–61,666,386, 1 gene, copy number 11: AL935212.2.
- chr9:63,581,254–64,413,142, 17 genes, copy number 6: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P.
- chr10:14,061–32,394,665, 537 genes, copy number 6 (broad region; genes not listed).
- chr10:32,887,273–38,783,108, 106 genes, copy number 5–8 (broad region; genes not listed).
- chr10:95,183,653–95,291,012, 4 genes, copy number 5: PAWRP1, ACSM6, AL157834.2, PDLIM1.
- chr11:560,404–564,025, 1 gene, copy number 8 (within-gene range 2–8): RASSF7.
- chr12:20,014,780–44,499,158, 352 genes, copy number 5–7 (broad region; genes not listed).
- chr12:65,466,820–68,487,863, 57 genes, copy number 5–6 (within-gene range 4–6): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2.
- chr12:132,083,540–132,131,639, 4 genes, copy number 5: AC137590.2, EP400P1, AC138466.5, AC138466.2.
- chr13:112,485,011–112,606,417, 2 genes, copy number 5: TUBGCP3, AL139384.2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:46,651,010–54,793,315, 153 genes, copy number 5 (broad region; genes not listed).
- chr14:66,111,557–66,131,716, 1 gene, copy number 5: LINC02290.
- chr15:34,520,608–34,521,791, 1 gene, copy number 6: DNM1P5.
- chr16:1,826,941–1,884,294, 4 genes, copy number 5 (within-gene range 2–5): FAHD1, MEIOB, AL031722.1, LINC00254.
- chr16:33,533,816–33,545,812, 2 genes, copy number 5: AC136944.1, AC136944.2.
- chr16:69,706,996–69,742,563, 3 genes, copy number 5 (within-gene range 2–5): NQO1, AC092115.2, AC092115.3.
- chr16:78,014,683–78,066,761, 4 genes, copy number 6: AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:83,968,632–84,145,192, 9 genes, copy number 5: NECAB2, SLC38A8, RNA5SP432, AC040169.4, MBTPS1, AC040169.3, AC040169.1, AC040169.2, HSDL1.
- chr16:85,027,751–85,149,443, 4 genes, copy number 5: KIAA0513, CIBAR2, LINC02139, AC026469.1.
- chr16:85,227,203–85,309,176, 4 genes, copy number 5: AC092275.1, COX6CP16, LINC00311, MIR5093.
- chr16:88,382,959–88,537,031, 4 genes, copy number 5: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr21:10,612,455–13,067,033, 6 genes, copy number 6: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr21:43,461,960–43,479,534, 1 gene, copy number 18 (within-gene range 1–18): LINC00313.
- chr22:15,489,990–15,492,564, 1 gene, copy number 5: YME1L1P1.
- chr22:18,650,023–18,719,341, 2 genes, copy number 8: PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 1,716. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
